Surgical pathology report (de-identified scan), TCGA case TCGA-UF-A7JJ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-UF-A7JJ-01A (Primary Tumor).

ICD-O-3
Carcinoma, squamous cell
keratinizing NOS 8071/3
Site: Larynx NOS C32.9
9/24/13

Collect date:

PATHOLOGY REPORT:

PRIMARY SITE: Larynx

1 - "Lymph Nodes – Level 2, 3, 4 and 5 – Right":

- Lymph node previously designated as "negative": uninvolved by metastatic carcinoma (0/1).
- Lymph node previously designated as "positive": metastatic squamous cell carcinoma with capsular involvement (1/1).
- Three of sixteen lymph nodes involved by metastatic carcinoma (3/16), with capsular involvement.
- Muscular tissue uninvolved by carcinoma.

2 - "Right recurrent lymph node":

- One of teen lymph nodes involved by metastatic carcinoma (1/10), with capsular involvement.

3 - "Lymph Nodes – Level 2, 3 and 4 – Left":

- Sixteen lymph nodes uninvolved by metastatic carcinoma (0/16).

4 - "Left recurrent lymph node":

- One of teen lymph nodes involved by metastatic carcinoma (1/10), without capsular involvement.

5 - "Larynx":

- Keratinizing squamous cell carcinoma:
- Histological grade 2.
- Tumor size 5.5 cm.
- Involving right vocal cord, cartilage tissue (thyroid, cricoid and arytenoid cartilages), skeletal muscle tissue, soft tissue and thyroid gland.
- Lymphatic invasion: present.
- Vascular invasion: not identified.
- Perineural invasion: not identified.
- Preepiglottic space uninvolved by neoplasia.
- Surgical margin uninvolved by neoplasia.

6 - "Tracheal margin extension":

- Uninvolved by neoplasia.

Source: NCI Genomic Data Commons file 36398402-2347-4ee8-8580-07da49678e72 (TCGA-UF-A7JJ.7A07186C-315E-470D-8C9E-48DBB89AFA7D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).